Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8345, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8345-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

- 1: SP: Right kidney, ureter and bladder cuff; nephroureterectomy [REDACTED]
- 2: SP: Retroperitoneal lipoma, right; excision [REDACTED]
- 3: SP: Lymph nodes, paracaval; excision [REDACTED]
- 4: SP: Lymph nodes, right common iliac; excision [REDACTED]
- 5: SP: Lymph nodes, precaval and interaortocaval; excision [REDACTED]
- 6: SP: Lymph nodes, suprahilar, and adrenal gland, right; excision [REDACTED]

DIAGNOSIS:

1. SP: Right kidney, ureter and bladder cuff; nephroureterectomy [REDACTED]

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 3.2 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion is also not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes and benign cortical cysts

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

Comment: Benign pelvi-calyceal system and ureter

2. SP: Soft tissue, retroperitoneum, right; excision [REDACTED]

Mature adipose tissue, 4.6cm.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

No atypia identified.

Comment: This part of the specimen was seen in consultation with [REDACTED], who concurs.

3. SP: Lymph nodes, paracaval; excision [REDACTED]

Lymph Nodes:

Not involved

Number of nodes examined:4

4. SP: Lymph nodes, right common iliac; excision [REDACTED]

Lymph Nodes:

Not involved

Number of nodes examined:2

5. SP: Lymph nodes, precaval and interaortocaval; excision [REDACTED]:

Lymph Nodes:

Not involved

Number of nodes examined:7

6. SP: Suprahilar nodes and right adrenal gland; excision [REDACTED]

Benign adrenal gland.

No lymph nodes identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received in fresh state for intraoperative consultation, labeled as "right kidney, ureter, and bladder cuff", and it consists of a total nephrectomy specimen weighing in total 502 g. The specimen surface is inked. No adrenal gland is identified. Kidney measures 11 x 6.0 x 3.9 cm, and the segment of ureter measures 19 cm in length and 0.8 cm in circumference. The distal end of the ureter may actually represent "bladder cuff". Sectioning reveals a well-circumscribed brown soft cortical mass measuring 3.2 x 3.2 x 2.9 cm in the lower medial aspect of the specimen. The majority of the tumor is in close contact with sinus fat, but frank invasion is grossly not identified. Grossly evident venous invasion is not seen. Perirenal fat is uninvolved. Background renal parenchyma shows mildly thinned cortex (0.7 cm) with sharp cortical medullary junction. Pelvic mucosa and ureteral mucosa appears grossly unremarkable. No possible lymph nodes are identified in the perirenal fat. The specimen is photographed. TPS is taken.

Summary of sections:

FSC -- frozen section control (tumor)

UM -- ureter margin

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

VM -- vascular margins
TSF -- tumor with sinus fat
T -- tumor
BG -- background renal parenchyma
P -- pelvic mucosa
U -- ureteral mucosa

2). The specimen is received in formalin, labeled as "right retroperitoneal lipoma", and it consists of a partially encapsulated nodule of adipose tissue measuring 4.6 x 2.3 x 2.0 cm. Sectioning reveals grossly unremarkable adipose tissue without fibrosis or hemorrhage. Representative sections are submitted.

Summary of sections:

U -- undesignated

3). The specimen is received in formalin, labeled as "paracaval lymph nodes", and it consists of multiple possible lymph nodes measuring up to 1.0 cm. Entire lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

4). The specimen is received in formalin, labeled as "right common iliac lymph nodes", and it consists of a single possible lymph node measuring 0.6 cm. Entire lymph node is submitted.

Summary of sections:

LN -- lymph node

Akihiko Yoshida, M.D.

5). The specimen is received in formalin, labeled as "precaval and inter-aortocaval lymph node", and it consists of multiple possible lymph nodes measuring up to 3.5 cm. The largest lymph node is trisected. Entire lymph nodes are submitted.

Summary of sections:

TLN -- trisected lymph node

LN -- lymph nodes

Akihiko Yoshida, M.D.

6). The specimen is received in formalin, labeled as "suprahilar nodes and right adrenal gland", and it consists of an adrenal gland and surrounding adipose tissue. Adrenal gland measures 7.0 x 3.5 x 1.6 cm and weighs 10.5 g after the removal of fat. Section reveals grossly unremarkable adrenal tissue. Surrounding adipose tissue does not contain grossly evident lymph nodes. Representative sections are submitted.

Summary of sections:

AD -- adrenal

F -- adipose tissue, slightly fibrotic area

Summary of Sections:

Part 1: SP: Right kidney, ureter and bladder cuff; nephroureterectomy

Block	Sect. Site	PCs
2	bg	2
1	fsc	1
1	p	1
1	t	1
6	tsf	6
1	u	1
1	um	1

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

1 vm 1

Part 2: SP: Retroperitoneal lipoma, right; excision

Block	Sect. Site	PCs
5	u	5

Part 3: SP: Lymph nodes, paracaval; excision

Block	Sect. Site	PCs
1	ln	1

Part 4: SP: Lymph nodes, right common iliac; excision

Block	Sect. Site	PCs
1	ln	1

Part 5: SP: Lymph nodes, precaval and interaortocaval; excision

Block	Sect. Site	PCs
1	ln	1
2	tlm	2

Part 6: SP: Lymph nodes, supra hilar, and adrenal gland, right; excision

Block	Sect. Site	PCs
1	ad	1
1	f	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Right kidney, ureter and bladder cuff **RENAL CORTICAL NEOPLASM.**
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 01ada9fd-11b3-4b62-bf75-7bf4c71f81a9 (TCGA-KL-8345.5F84D5AC-C1D1-4009-95FF-B0AE508A1B2A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).